Somatic mutation profile of tumor specimen MP2PRT-PARCBE-TMP1-A (aliquot MP2PRT-PARCBE-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARCBE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lymphoid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,823 days).
Specimen MP2PRT-PARCBE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21c05e05-14b8-4edc-b7a5-906e11636053.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARCBE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARCBE-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d167d562-ddcd-4289-a01e-9b7d878c72d2

The open-access MAF lists 41 somatic variants for this specimen: 26 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 13, Frame Shift Del 1, Nonsense Mutation 1, Frame Shift Ins 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD18B | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.809); catalogued as rs774619870; called by muse, mutect2, varscan2
- BRWD3 | c.3592C>T p.R1198C | Missense Mutation (SNP) | VAF 81/230 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1386861640; called by muse, mutect2, varscan2
- CCDC105 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV52965272; called by muse, mutect2, varscan2
- COL13A1 | c.1114G>A p.E372K (on ENST00000398978 / NM_001130103.2; = p.E315K on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/425 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1236197890; called by muse, mutect2
- CSGALNACT1 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 15/348 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.329); catalogued as COSV100174968; called by muse, mutect2
- HTR1A | c.910C>A p.H304N | Missense Mutation (SNP) | VAF 69/553 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV60500928; called by muse, mutect2, varscan2
- KRTCAP3 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 40/388 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1213041908, COSV99275238; called by muse, mutect2
- MBTPS2 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); catalogued as COSV65267411; called by muse, mutect2, varscan2
- MUC5B | c.10369C>T p.R3457W | Missense Mutation (SNP) | VAF 132/857 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs756968127, COSV101500266, COSV71590189; called by muse, varscan2
- NT5C3B | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs782173364, COSV54057033; called by muse, mutect2
- PCNT | c.3553G>A p.E1185K | Missense Mutation (SNP) | VAF 31/543 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as rs920374957; ClinVar: likely benign; called by muse, mutect2
- SH3RF2 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 105/527 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs150009220, COSV63041803; called by muse, mutect2, varscan2
- TRIM49C | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 38/369 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as rs1345786121; called by muse, mutect2, varscan2
- ZNF782 | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 82/492 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100001630, COSV56654489; called by muse, mutect2, varscan2
- ZNF782 | c.1493G>A p.R498K | Missense Mutation (SNP) | VAF 84/430 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV56651717; called by muse, mutect2, varscan2
- ZNF782 | c.989G>C p.R330T | Missense Mutation (SNP) | VAF 60/355 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs770441383, COSV56651830; called by muse, mutect2, varscan2
- CSMD1 | c.6446_6447insGGGC p.Y2149* (on ENST00000520002; = p.Y2148* on NM_033225.6) | Nonsense Mutation (INS) | VAF 55/185 reads (30%) | called by mutect2, pindel, varscan2
- DACH1 | c.851C>G p.S284C | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); called by muse, mutect2
- LEF1 | c.928A>G p.M310V | Missense Mutation (SNP) | VAF 28/426 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2
- LNPEP | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 17/471 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRATD2 | c.165dup p.G56Wfs*84 | Frame Shift Ins (INS) | VAF 96/504 reads (19%) | called by pindel, varscan2
- SFXN1 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SIAE | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLC25A1 | c.168C>G p.D56E | Missense Mutation (SNP) | VAF 83/514 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TBL1XR1 | c.420_423delinsCC p.I141Rfs*3 | Frame Shift Del (DEL) | VAF 99/269 reads (37%) | called by pindel, varscan2*
- TRAJ10 | chr14:22533495 TGATACTC>CCCCGGG | Missense Mutation (DEL) | VAF 120/321 reads (37%) | called by pindel, varscan2*
- B4GALNT4 | c.1536G>A p.P512= | Silent (SNP) | VAF 72/619 reads (12%) | catalogued as rs1332863406, COSV57322629; called by muse, mutect2, varscan2
- DPRX | c.516C>T p.C172= | Silent (SNP) | VAF 100/310 reads (32%) | catalogued as rs755247548, COSV64949428; called by muse, mutect2, varscan2
- FAM222A | c.831G>T p.G277= | Silent (SNP) | VAF 182/578 reads (31%) | catalogued as rs767676227; called by muse, mutect2, varscan2
- FLT4 | c.102C>T p.I34= | Silent (SNP) | VAF 40/366 reads (11%) | catalogued as rs1400540057; called by muse, mutect2, varscan2
- GUSB | c.1557G>T p.L519= | Silent (SNP) | VAF 18/381 reads (5%) | called by muse, mutect2
- IGKV1OR2-108 | chr2:113406872 del TCACAG | Silent (DEL) | VAF 50/92 reads (54%) | called by mutect2, pindel, varscan2
- L3MBTL4 | c.570A>G p.K190= | Silent (SNP) | VAF 50/322 reads (16%) | catalogued as rs773409850; called by muse, mutect2, varscan2
- MYO15A | c.5506C>T p.L1836= | Silent (SNP) | VAF 30/226 reads (13%) | catalogued as COSV99234714; called by muse, mutect2, varscan2
- NSD2 | c.1590G>A p.K530= | Silent (SNP) | VAF 14/328 reads (4%) | catalogued as COSV100374126; called by muse, mutect2
- P2RX6 | c.277C>A p.R93= | Silent (SNP) | VAF 108/327 reads (33%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.384C>T p.P128= | Silent (SNP) | VAF 30/446 reads (7%) | catalogued as rs758737259, COSV100782689; called by muse, mutect2
- SYNE1 | c.6153T>C p.A2051= (on ENST00000367255 / NM_182961.4; = p.A2058= on NM_033071.3) | Silent (SNP) | VAF 107/363 reads (29%) | called by muse, mutect2, varscan2
- TPRN | c.276C>T p.L92= | Silent (SNP) | VAF 22/830 reads (3%) | catalogued as rs1176910904; called by muse, mutect2
- IGHV3-53 | chr14:106592675 ins TCTTGGGGA | 3'Flank (INS) | VAF 12/64 reads (19%) | called by mutect2, pindel
- UNC13B | c.762-2584G>T | Intron (SNP) | VAF 50/273 reads (18%) | called by muse, mutect2, varscan2
